Gene-level copy-number profile of tumor specimen TCGA-OR-A5LD-01A from TCGA case TCGA-OR-A5LD, project TCGA-ACC (Adrenocortical Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adrenal cortical carcinoma; Tissue or organ of origin: Cortex of adrenal gland; Age at diagnosis: 52.3 years (19,111 days).
Specimen TCGA-OR-A5LD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ACC.ab185b04-9b48-4c41-989e-1b2e4590ee5a.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-OR-A5LD-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 807 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/083df819-c731-468a-a1c4-e47f4fc4e227

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 2,389; copy number 2: 7,932; copy number 3: 28,374; copy number 4: 12,869; copy number 5: 7,423; copy number 7: 247; copy number 8: 169; copy number 9: 8; copy number 10: 189; copy number 11: 148; copy number 12: 5; copy number 13: 63.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-OR-A5LD-01A-11D-A29H-01): tumor purity 0.94, ploidy 3.26, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 829 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:71,132,144–76,362,113, 144 genes, copy number 10 (broad region; genes not listed).
- chr16:61,638,233–62,357,746, 8 genes, copy number 9: AC092125.2, CDH8, AC092125.1, RN7SKP76, AC012174.1, RNU6-21P, AC009161.2, AC009161.1.
- chr16:64,364,781–70,372,582, 224 genes, copy number 8–13 (within-gene range 2–13) (broad region; genes not listed).
- chr19:14,732,392–19,979,610, 292 genes, copy number 7–10 (broad region; genes not listed).
- chr19:20,432,552–20,571,095, 1 gene, copy number 8 (within-gene range 3–8): AC008554.1.
- chr19:20,535,825–24,163,425, 160 genes, copy number 8 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 3. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
